Somatic mutation profile of tumor specimen TCGA-X7-A8D9-01A (aliquot TCGA-X7-A8D9-01A-11D-A423-09) from TCGA case TCGA-X7-A8D9, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus.
Specimen TCGA-X7-A8D9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 545f0d3b-3248-47d4-a51f-622c0f60e873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8D9-10A (Blood Derived Normal), aliquot TCGA-X7-A8D9-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63d0f500-a8f7-4ec7-8a83-ca64187db452

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 7, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 53/392 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- GRIP1 | c.2032C>T p.R678C (on ENST00000359742 / NM_001379345.1; = p.R626C on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs991022034; called by muse, mutect2, varscan2
- PI15 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs529529830, COSV99478046, COSV99478210; called by mutect2, varscan2
- TBL3 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.235); catalogued as rs1401727000; called by mutect2, varscan2
- TMCO3 | c.1990A>G p.I664V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs142845599; called by muse, mutect2, varscan2
- ALPP | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CCDC144A | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.323); called by muse, mutect2
- CTRL | c.713del p.N238Tfs*24 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- CYFIP2 | c.15C>A p.V5= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- FGD1 | c.1329C>A p.R443= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- OR1J2 | c.609G>T p.G203= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- PPP1R36 | c.1014A>G p.Q338= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, varscan2
- SLC10A3 | c.1062C>T p.V354= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1557213456; called by muse, mutect2, varscan2
- ST3GAL1 | c.255G>A p.L85= | Silent (SNP) | VAF 4/27 reads (15%) | called by mutect2, varscan2
- TCF3 | c.1953C>T p.A651= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs562957668; called by muse, mutect2, varscan2
